Somatic mutation profile of tumor specimen TCGA-B8-5545-01A (aliquot TCGA-B8-5545-01A-01D-1669-08) from TCGA case TCGA-B8-5545, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 42.1 years (15,376 days).
Specimen TCGA-B8-5545-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b3c91d05-74d1-45bc-87a2-e8de09253367.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B8-5545-10A (Blood Derived Normal), aliquot TCGA-B8-5545-10A-01D-1669-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0a4fe4f9-d7d6-4730-b146-b610304c325e

The open-access MAF lists 28 somatic variants for this specimen: 20 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 7, Frame Shift Del 3, Nonsense Mutation 2, In Frame Del 1, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ELOC | c.237C>A p.Y79* | Nonsense Mutation (SNP) | VAF 11/38 reads (29%) | hotspot (GDC flag); catalogued as COSV53022628; called by muse, mutect2, varscan2
- ELOC | c.236A>T p.Y79F | Missense Mutation (SNP) | VAF 11/38 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.16); catalogued as rs1057519973, COSV53022646, COSV53022661, COSV53024355; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ATPAF2 | c.406G>A p.D136N | Missense Mutation (SNP) | VAF 28/148 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.911); catalogued as COSV71398399; called by muse, mutect2, varscan2
- BMP2K | c.3007A>G p.S1003G | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as COSV55008446; called by muse, mutect2, varscan2
- GLI3 | c.400C>T p.P134S | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67885241; called by muse, mutect2, varscan2
- IARS1 | c.2557A>T p.I853F | Missense Mutation (SNP) | VAF 31/189 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.11); catalogued as COSV65112768; called by muse, mutect2
- IARS1 | c.2555T>C p.V852A | Missense Mutation (SNP) | VAF 31/192 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.768); catalogued as COSV65112770; called by muse, mutect2
- LGR4 | c.1718C>T p.S573F | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.564); catalogued as COSV64863415; called by muse, mutect2, varscan2
- MAP4K3 | c.1237G>T p.E413* | Nonsense Mutation (SNP) | VAF 22/150 reads (15%) | catalogued as COSV55709915; called by muse, mutect2, varscan2
- MBP | c.512T>C p.I171T (on ENST00000355994 / NM_001025101.2; = p.I38T on NM_002385.3) | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV62828512; called by muse, mutect2, varscan2
- NFXL1 | c.2626G>A p.E876K | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV67431061; called by muse, mutect2, varscan2
- OR52K1 | c.284A>G p.N95S | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56902942; called by muse, mutect2
- SLC30A9 | c.652T>G p.F218V | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT tolerated (0.49); PolyPhen benign (0.283); catalogued as COSV52553956; called by muse, mutect2
- SRGAP3 | c.2546G>A p.G849E | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT tolerated, low confidence (0.97); PolyPhen possibly damaging (0.863); catalogued as COSV64530363; called by muse, mutect2, varscan2
- YLPM1 | c.768T>G p.N256K | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as COSV53106004; called by muse, mutect2, varscan2
- BCORL1 | c.2301_2302insT p.K768* | Frame Shift Ins (INS) | VAF 7/27 reads (26%) | called by pindel, varscan2
- CASP8AP2 | c.4018_4029del p.T1340_K1343del | In Frame Del (DEL) | VAF 10/50 reads (20%) | called by mutect2, pindel, varscan2
- CSMD2 | c.3087_3096del p.I1029Mfs*30 | Frame Shift Del (DEL) | VAF 6/52 reads (12%) | called by mutect2, pindel
- TP53BP1 | c.4428_4429del p.L1477Rfs*8 | Frame Shift Del (DEL) | VAF 35/164 reads (21%) | called by mutect2, pindel, varscan2
- ZBTB37 | c.15del p.N6Tfs*14 | Frame Shift Del (DEL) | VAF 4/32 reads (13%) | called by mutect2, pindel
- ANK3 | c.5370G>A p.Q1790= | Silent (SNP) | VAF 25/145 reads (17%) | catalogued as COSV55044165, COSV55084821; called by muse, mutect2, varscan2
- CUBN | c.8910T>C p.R2970= | Silent (SNP) | VAF 3/27 reads (11%) | catalogued as COSV64707811; called by muse, mutect2
- FGD1 | c.2403G>A p.Q801= | Silent (SNP) | VAF 3/37 reads (8%) | catalogued as rs1229463212, COSV64308075; called by muse, mutect2
- PPARG | c.327G>A p.E109= (on ENST00000287820 / NM_015869.5; = p.E79= on NM_005037.7) | Silent (SNP) | VAF 9/53 reads (17%) | catalogued as COSV55140971; called by muse, mutect2, varscan2
- PRSS54 | c.108C>T p.S36= | Silent (SNP) | VAF 4/63 reads (6%) | catalogued as COSV54688906; called by muse, mutect2
- SETBP1 | c.1941A>G p.K647= | Silent (SNP) | VAF 16/80 reads (20%) | catalogued as COSV56312953; called by muse, mutect2, varscan2
- SLITRK6 | c.340C>T p.L114= | Silent (SNP) | VAF 37/153 reads (24%) | catalogued as COSV68389339; called by muse, mutect2, varscan2
- SNORD116-19 | n.78G>T | RNA (SNP) | VAF 46/256 reads (18%) | called by muse, mutect2, varscan2
